Somatic mutation profile of tumor specimen MMRF_1021_1_BM_CD138pos (aliquot MMRF_1021_1_BM_CD138pos_T2_KAS5U_L02366) from MMRF case MMRF_1021, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.1 years (19,778 days).
Specimen MMRF_1021_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a56a291-052f-46c5-bb6b-dad97a90481f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1021_2_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1021_2_PB_CD3pos_C1_KAS5U_L02374; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acf1d278-55c9-4407-ad78-d4e7dac9ca1e

The open-access MAF lists 125 somatic variants for this specimen: 58 protein-altering or splice-affecting, 9 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 35, Intron 10, Silent 9, 5'Flank 4, 5'UTR 4, 3'Flank 4, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F22 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as rs745368359, CM160335; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACTG1 | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs148759022; called by muse, mutect2, varscan2
- ASH1L | c.2836G>T p.D946Y | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV100853227; called by muse, mutect2, varscan2
- CHRNB4 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55714899; called by muse, mutect2
- DCSTAMP | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 112/292 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.702); catalogued as rs765750442, COSV52579527; called by muse, mutect2, varscan2
- DNAJC12 | c.503-2A>G p.X168_splice | Splice Site (SNP) | VAF 79/150 reads (53%) | catalogued as COSV99830610; called by muse, mutect2, varscan2
- IGHV1-18 | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs190934741; called by muse, mutect2
- IGKJ2 | c.35T>C p.I12T | Missense Mutation (SNP) | VAF 66/132 reads (50%) | catalogued as rs371587575; called by muse, varscan2
- IGLL5 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as rs552972168, COSV73251026, COSV73251190; called by muse, mutect2, varscan2
- JARID2 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1337884490; called by muse, mutect2
- KLK5 | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60449889; called by muse, mutect2, varscan2
- KRAS | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV55511879; called by muse, mutect2
- MMRN2 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs764221591; called by muse, mutect2, varscan2
- MYH14 | c.3809G>A p.R1270Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs747431212; called by muse, mutect2
- MYOM2 | c.1771C>G p.H591D | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.599); catalogued as rs1244122002; called by muse, mutect2, varscan2
- NOL10 | c.2028C>A p.H676Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV100630213; called by muse, mutect2
- OR4C15 | c.1082T>C p.V361A (on ENST00000314644; = p.V307A on NM_001001920.2) | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as COSV58954434; called by muse, mutect2, varscan2
- OR6C74 | c.702dup p.A235Sfs*36 | Frame Shift Ins (INS) | VAF 40/144 reads (28%) | catalogued as rs1286886511; called by mutect2, varscan2
- PTPRS | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.513); catalogued as rs760549393; called by muse, mutect2, varscan2
- SLC12A1 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 11/293 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324801522, COSV57710433; called by muse, mutect2
- SPIC | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs755944301; called by muse, mutect2, varscan2
- STIL | c.3751A>G p.I1251V | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142210835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STK35 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV55690586; called by muse, varscan2
- SYT16 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1413075127, COSV70855944; called by muse, mutect2
- TTN | c.16103C>A p.T5368N (on ENST00000591111; = p.T4441N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | PolyPhen possibly damaging (0.744); catalogued as rs755271632; called by muse, mutect2, varscan2
- USP37 | c.1670+2T>G p.X557_splice | Splice Site (SNP) | VAF 46/94 reads (49%) | catalogued as rs1449267034; called by muse, varscan2
- ZNF541 | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs922285307, COSV54548383; called by muse, mutect2
- ANKRD50 | c.1210A>G p.K404E | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ARHGAP42 | c.107T>C p.I36T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- B3GAT1 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMPR1A | c.932A>G p.Y311C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- COL28A1 | c.2767A>T p.S923C | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- DCBLD1 | c.1957C>A p.Q653K | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- DNAH5 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.147); called by muse, mutect2
- EGR4 | c.1132_1133del p.D378Lfs*6 (on ENST00000545030; = p.D275Lfs*6 on NM_001965.4) | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- FN1 | c.1441G>T p.G481* | Nonsense Mutation (SNP) | VAF 39/117 reads (33%) | called by muse, mutect2, varscan2
- HM13 | c.603C>A p.H201Q | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- HTT | c.2015A>C p.Q672P | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- IGHV2-70D | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by mutect2, varscan2
- IGKV2D-29 | c.344A>T p.Q115L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- IGKV4-1 | c.184_186delinsGGCTTCGT p.Y62Gfs*? | Frame Shift Ins (INS) | VAF 27/81 reads (33%) | called by pindel, varscan2*
- IGLV3-1 | c.239T>C p.F80S | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KNTC1 | c.3473C>A p.T1158N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PCLO | c.8557A>C p.I2853L | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- PGM1 | c.883A>C p.M295L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PIK3R1 | c.1316A>G p.E439G (on ENST00000521381 / NM_181523.3; = p.E169G on NM_181504.4) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- PRADC1 | c.68del p.G23Afs*13 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- RBM20 | c.3500G>A p.G1167E | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SCYL1 | c.1838C>A p.T613N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO1A2 | c.1971G>T p.K657N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- SPIRE2 | c.1943G>C p.W648S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- STARD9 | c.12061A>T p.R4021W | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SYNE1 | c.22477C>A p.Q7493K (on ENST00000367255 / NM_182961.4; = p.Q7422K on NM_033071.3) | Missense Mutation (SNP) | VAF 9/282 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TNIK | c.480G>T p.L160F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VPS4A | c.345T>C p.G115= | Splice Region (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- ZNF681 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF773 | c.871G>C p.V291L | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANK2 | c.6063A>G p.P2021= | Silent (SNP) | VAF 43/176 reads (24%) | called by muse, mutect2, varscan2
- CLSTN2 | c.694C>T p.L232= | Silent (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- DCC | c.2160A>C p.L720= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- GARRE1 | c.909C>T p.H303= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as rs144093159; called by muse, mutect2, varscan2
- GFOD2 | c.75A>T p.A25= | Silent (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- LAMA1 | c.3351C>T p.A1117= | Silent (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- PCDH19 | c.1176G>C p.V392= | Silent (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- ROBO1 | c.1386G>A p.V462= | Silent (SNP) | VAF 41/140 reads (29%) | called by muse, mutect2, varscan2
- SYNE1 | c.6483T>C p.S2161= (on ENST00000367255 / NM_182961.4; = p.S2168= on NM_033071.3) | Silent (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- AIM2 | c.-5G>A | 5'UTR (SNP) | VAF 87/517 reads (17%) | called by muse, mutect2, varscan2
- ALG12 | c.993-44del | Intron (DEL) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- ANKLE2 | c.1892-650G>T | Intron (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- ASH1L | c.5828+4370_5828+4377del | Intron (DEL) | VAF 9/74 reads (12%) | called by mutect2, pindel, varscan2
- BCL7A | chr12:122021136 T>C | 5'Flank (SNP) | VAF 50/103 reads (49%) | catalogued as rs552023208; called by muse, mutect2, varscan2
- BEND4 | c.*5154G>A | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- CAMK4 | c.*3145A>G | 3'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- CAVIN2 | c.*380A>T | 3'UTR (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- CCAR1 | c.*169T>G | 3'UTR (SNP) | VAF 35/57 reads (61%) | called by muse, mutect2, varscan2
- CDCP1 | c.*35A>C | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- COL11A1 | c.*349G>A | 3'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- DHX40P1 | n.629T>A | RNA (SNP) | VAF 48/168 reads (29%) | called by muse, mutect2, varscan2
- DUOX1 | c.*568C>T | 3'UTR (SNP) | VAF 30/149 reads (20%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.*1039T>C | 3'UTR (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- ERMN | c.*2502A>G | 3'UTR (SNP) | VAF 4/85 reads (5%) | called by muse, mutect2
- FAM166A | c.272-18G>T | Intron (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- FREM2 | c.*4579C>T | 3'UTR (SNP) | VAF 46/53 reads (87%) | called by muse, mutect2, varscan2
- G6PC2 | c.*21C>T | 3'UTR (SNP) | VAF 65/233 reads (28%) | catalogued as rs1323044519; called by muse, mutect2, varscan2
- HJV | c.*372A>G | 3'UTR (SNP) | VAF 11/146 reads (8%) | catalogued as rs747020380; ClinVar: uncertain significance; called by muse, mutect2
- HOATZ | c.453-385C>T | Intron (SNP) | VAF 21/70 reads (30%) | catalogued as rs956068334, COSV60440559; called by muse, mutect2, varscan2
- HRH2 | chr5:175685651 C>T | 3'Flank (SNP) | VAF 66/156 reads (42%) | called by muse, mutect2, varscan2
- HS3ST1 | c.*4351C>T | 3'UTR (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- HS6ST3 | c.*53T>A | 3'UTR (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- HTR3A | c.*112_*115del | 3'UTR (DEL) | VAF 6/75 reads (8%) | catalogued as rs1229128849; called by mutect2, pindel
- HTRA2 | chr2:74529795 C>A | 5'Flank (SNP) | VAF 60/127 reads (47%) | called by muse, mutect2, varscan2
- KIAA1143 | c.*4413G>A | 3'UTR (SNP) | VAF 123/306 reads (40%) | called by muse, mutect2, varscan2
- MIR6073 | chr11:15966543 G>T | 3'Flank (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- MROH2B | c.-41A>G | 5'UTR (SNP) | VAF 22/251 reads (9%) | called by muse, mutect2
- NKX2-1 | chr14:36513620 del GGCTGAGGCATTCCCTGCCCCCACCCCCCTCCTGGCCTTGA | 3'Flank (DEL) | VAF 21/76 reads (28%) | called by mutect2, pindel
- NOVA1 | c.447+75G>T | Intron (SNP) | VAF 31/77 reads (40%) | catalogued as rs893101896; called by muse, mutect2, varscan2
- PCDH18 | c.*45G>C | 3'UTR (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
- PLD1 | c.2882+769A>T | Intron (SNP) | VAF 67/241 reads (28%) | called by muse, mutect2, varscan2
- PNN | c.*112A>C | 3'UTR (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- POGLUT1 | c.*1658C>A | 3'UTR (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- PPCS | chr1:42456146 A>T | 5'Flank (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- PRDM16 | c.*965C>G | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- PROS1 | c.*252C>A | 3'UTR (SNP) | VAF 39/109 reads (36%) | called by muse, mutect2, varscan2
- PUS10 | c.*350T>G | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- RGP1 | c.*5444_*5447del | 3'UTR (DEL) | VAF 32/81 reads (40%) | called by mutect2, pindel, varscan2
- RHOB | c.-112G>C | 5'UTR (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- RIC8A | c.-1122G>T | 5'UTR (SNP) | VAF 31/190 reads (16%) | called by muse, mutect2, varscan2
- RN7SL860P | chr19:22600282 C>G | 5'Flank (SNP) | VAF 19/30 reads (63%) | called by muse, mutect2, varscan2
- RRM2B | c.*2985T>A | 3'UTR (SNP) | VAF 57/242 reads (24%) | called by muse, mutect2, varscan2
- SEMA5A | c.*155G>A | 3'UTR (SNP) | VAF 47/103 reads (46%) | catalogued as rs891504688; called by muse, mutect2, varscan2
- SMC1A | c.*1736A>T | 3'UTR (SNP) | VAF 28/33 reads (85%) | called by muse, mutect2, varscan2
- SSBP2 | c.*4821G>T | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- ST6GAL1 | c.706-8268C>T | Intron (SNP) | VAF 9/36 reads (25%) | catalogued as rs1284207561; called by muse, varscan2
- ST6GAL1 | c.706-8267C>A | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, varscan2
- TAFA4 | c.*397T>C | 3'UTR (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- TCHP | c.*1409G>A | 3'UTR (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- THADA | c.2312-2443A>C | Intron (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- TMEM132D | c.*394G>C | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- TSPAN14 | chr10:80519424 C>A | 3'Flank (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- UBE2V2 | c.*698A>T | 3'UTR (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- UTP25 | c.*130T>C | 3'UTR (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- WIPF2 | c.*267G>A | 3'UTR (SNP) | VAF 32/85 reads (38%) | catalogued as rs1230526015; called by muse, mutect2, varscan2
- ZADH2 | c.*2840G>C | 3'UTR (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- ZBED3 | c.*2639G>A | 3'UTR (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
